Somatic mutation profile of tumor specimen TCGA-BP-5173-01A (aliquot TCGA-BP-5173-01A-01D-1429-08) from TCGA case TCGA-BP-5173, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 75.1 years (27,436 days).
Specimen TCGA-BP-5173-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 18063fc6-8c03-44dd-9236-c0b789c03570.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-5173-11A (Solid Tissue Normal), aliquot TCGA-BP-5173-11A-01D-1429-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7aa78aa0-8227-44bc-a370-73e16904d285

The open-access MAF lists 86 somatic variants for this specimen: 62 protein-altering or splice-affecting, 23 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 23, Frame Shift Del 1, Frame Shift Ins 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRV1 | c.5375T>A p.I1792N | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67981496; called by muse, mutect2, varscan2
- ATM | c.8152G>C p.G2718R | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53726783, COSV53734460; called by muse, mutect2, varscan2
- ATP10D | c.739A>T p.S247C | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV56705468; called by muse, mutect2, varscan2
- BRD8 | c.701T>A p.L234Q (on ENST00000254900 / NM_139199.2; = p.L307Q on NM_006696.4) | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.981); catalogued as COSV50146102; called by muse, mutect2, varscan2
- C17orf98 | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766541161; called by muse, mutect2, varscan2
- C1orf112 | c.1754T>A p.V585E | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV53677489; called by muse, mutect2, varscan2
- CCDC173 | c.1125A>C p.K375N | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV71653159; called by mutect2, varscan2
- CD5L | c.16T>C p.S6P | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV100941029; called by muse, mutect2, varscan2
- CERS3 | c.1048G>C p.E350Q | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.528); catalogued as COSV52566329, COSV52568330; called by muse, mutect2
- CREBZF | c.1009T>G p.S337A | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV52629160; called by muse, mutect2, varscan2
- CXCL11 | c.67C>A p.P23T | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.254); catalogued as COSV60666246; called by muse, mutect2, varscan2
- DBH | c.1574A>G p.E525G | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV67548973; called by muse, mutect2, varscan2
- DDR2 | c.2468C>T p.S823F | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.191); catalogued as CD144594, COSV100906994, COSV63370125; called by muse, mutect2, varscan2
- DNASE2B | c.50T>C p.L17P | Missense Mutation (SNP) | VAF 58/126 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as COSV65743308; called by muse, mutect2, varscan2
- DPY19L3 | c.1784A>G p.N595S | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.998); catalogued as COSV60475439; called by muse, mutect2, varscan2
- DUSP10 | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.454); catalogued as COSV60457086; called by muse, mutect2, varscan2
- F8 | c.4385T>A p.L1462H | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.72); catalogued as COSV64271097; called by muse, mutect2, varscan2
- FBLN1 | c.1195G>A p.D399N | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53045068; called by muse, mutect2, varscan2
- FBXO43 | c.1472G>A p.G491D | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71053642; called by muse, mutect2
- GALNT7 | c.1081C>A p.L361I | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV53928100; called by muse, mutect2, varscan2
- GLCE | c.1442C>G p.S481C | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs1181013309, COSV55945012; called by muse, mutect2, varscan2
- GLIPR1L1 | c.391T>G p.C131G | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56881007, COSV56884139; called by muse, mutect2, varscan2
- HDAC6 | c.1529T>C p.I510T | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61928117; called by muse, mutect2, varscan2
- HIPK1 | c.178C>A p.H60N | Missense Mutation (SNP) | VAF 87/166 reads (52%) | SIFT tolerated (0.32); PolyPhen benign (0.034); catalogued as COSV65783907; called by muse, mutect2, varscan2
- HIPK2 | c.875A>G p.K292R | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs761865721, COSV61226559; called by muse, mutect2, varscan2
- HMCN1 | c.16178A>T p.H5393L | Missense Mutation (SNP) | VAF 38/222 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV54887283; called by muse, mutect2, varscan2
- HMOX1 | c.606G>T p.E202D | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53339373; called by muse, mutect2, varscan2
- HROB | c.1717T>A p.Y573N | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV55369145; called by muse, mutect2, varscan2
- IQCN | c.1936C>G p.H646D | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV66573169; called by muse, mutect2, varscan2
- KCNG4 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs777359377, COSV57582777, COSV57585394; called by mutect2, varscan2
- MGAT4C | c.1364G>A p.C455Y | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59831256; called by muse, mutect2, varscan2
- MUC17 | c.6121G>A p.E2041K | Missense Mutation (SNP) | VAF 49/349 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as rs865953839, COSV60283709; called by muse, mutect2, varscan2
- NABP1 | c.523A>C p.I175L | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV57138581; called by mutect2, varscan2
- OGDHL | c.2168G>A p.S723N | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0.006); catalogued as COSV65101662; called by muse, mutect2, varscan2
- OGT | c.104G>T p.G35V | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); catalogued as COSV65480106; called by muse, mutect2, varscan2
- OR1D2 | c.101T>C p.M34T | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as rs754622759, COSV58921354; called by muse, mutect2, varscan2
- OR4K13 | c.353T>C p.M118T | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as rs759784053, COSV59859279; called by muse, mutect2, varscan2
- PLVAP | c.307C>A p.L103M | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.357); catalogued as COSV53084076; called by muse, mutect2, varscan2
- POLH | c.865C>A p.H289N | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as COSV64779071, COSV64779384; called by muse, mutect2, varscan2
- PRTG | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 37/211 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV66837338; called by muse, mutect2, varscan2
- SAT1 | c.356G>A p.R119K | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63380640; called by muse, mutect2, varscan2
- SDHD | c.227T>A p.L76H | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54777726; called by muse, mutect2, varscan2
- SERPINB5 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.889); catalogued as COSV66975192; called by muse, mutect2, varscan2
- SLF2 | c.3426C>A p.D1142E | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as rs946838397, COSV53271895, COSV99489454; called by muse, mutect2, varscan2
- SNX27 | c.1565A>G p.K522R | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.075); catalogued as COSV64325913; called by muse, mutect2, varscan2
- SPHKAP | c.498C>A p.N166K | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.622); catalogued as COSV60872706; called by muse, mutect2, varscan2
- SVEP1 | c.4895C>G p.P1632R | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV100990657; called by muse, mutect2, varscan2
- SYNPO2 | c.427G>C p.A143P | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV61108268; called by muse, mutect2
- TARBP1 | c.2914A>T p.M972L | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50181075; called by muse, mutect2, varscan2
- THOC1 | c.1959T>G p.N653K | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.025); catalogued as COSV55274462, COSV55278087; called by muse, mutect2
- TMEM184C | c.1088T>G p.F363C | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as COSV56853314; called by muse, mutect2, varscan2
- TSPOAP1 | c.1718G>A p.G573D | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); catalogued as rs1204865958, COSV52105993; called by muse, mutect2, varscan2
- TSPOAP1 | c.1717G>A p.G573S | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as COSV52106005; called by muse, mutect2, varscan2
- TTC32 | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs746455461, COSV61267512, COSV61267751; called by muse, mutect2, varscan2
- TTN | c.41071C>A p.L13691M (on ENST00000591111; = p.L6267M on NM_003319.4) | Missense Mutation (SNP) | VAF 15/105 reads (14%) | PolyPhen probably damaging (0.925); catalogued as COSV59955798; called by muse, mutect2, varscan2
- UBE3B | c.2707T>A p.F903I | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61073529; called by muse, mutect2, varscan2
- ZNF652 | c.1205C>A p.S402Y | Missense Mutation (SNP) | VAF 58/201 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV62946492; called by muse, mutect2, varscan2
- ZNF761 | c.355T>A p.L119M | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.758); catalogued as COSV100483280, COSV61887925; called by muse, mutect2, varscan2
- ZNF804A | c.1359T>G p.I453M | Missense Mutation (SNP) | VAF 69/135 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV56441096; called by muse, mutect2, varscan2
- ARRDC3 | c.237dup p.E80Rfs*6 | Frame Shift Ins (INS) | VAF 16/147 reads (11%) | called by mutect2, varscan2
- B3GALT2 | c.1241del p.G414Afs*30 | Frame Shift Del (DEL) | VAF 35/142 reads (25%) | called by mutect2, pindel, varscan2
- CATSPERD | c.983_985del p.I328del | In Frame Del (DEL) | VAF 7/42 reads (17%) | called by mutect2, pindel, varscan2
- CHST4 | c.324C>A p.V108= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as COSV58296693; called by muse, mutect2, varscan2
- CHSY3 | c.1545G>T p.R515= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as COSV59274689; called by muse, mutect2, varscan2
- CNTNAP2 | c.1224T>C p.G408= | Silent (SNP) | VAF 34/90 reads (38%) | catalogued as COSV62159056; called by muse, mutect2, varscan2
- COG1 | c.1776T>C p.I592= | Silent (SNP) | VAF 26/80 reads (33%) | catalogued as COSV55428892; called by muse, mutect2, varscan2
- DAPK1 | c.3666C>T p.V1222= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV63786063; called by muse, mutect2, varscan2
- FBN2 | c.849C>T p.I283= | Silent (SNP) | VAF 43/131 reads (33%) | catalogued as rs769355095, COSV52502945, COSV52520239; called by muse, mutect2, varscan2
- GJA10 | c.327G>A p.R109= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as rs1329815734, COSV65354950; called by muse, mutect2, varscan2
- LCOR | c.837A>G p.V279= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV63630493; called by muse, mutect2, varscan2
- MAF | c.90T>C p.F30= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as COSV58153493; called by muse, mutect2, varscan2
- MYO5B | c.1839C>T p.S613= | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as rs577718838, COSV53214422; called by muse, mutect2, varscan2
- NBEAL1 | c.4578A>T p.I1526= | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as COSV71373983; called by muse, mutect2, varscan2
- OR10G9 | c.558G>A p.L186= | Silent (SNP) | VAF 29/177 reads (16%) | catalogued as COSV66685985; called by muse, mutect2, varscan2
- PCDHB8 | c.1653G>T p.L551= | Silent (SNP) | VAF 49/240 reads (20%) | catalogued as COSV50758566; called by mutect2, varscan2
- PDIA3 | c.1083G>A p.L361= | Silent (SNP) | VAF 26/76 reads (34%) | catalogued as COSV55855254; called by muse, mutect2, varscan2
- PLG | c.1503A>G p.P501= | Silent (SNP) | VAF 29/95 reads (31%) | catalogued as rs150227219, COSV51981780; called by muse, mutect2, varscan2
- SAT1 | c.357G>A p.R119= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as COSV63380642; called by muse, mutect2, varscan2
- SLC13A1 | c.1521C>T p.A507= | Silent (SNP) | VAF 20/39 reads (51%) | catalogued as COSV52009513; called by muse, mutect2, varscan2
- SLC35G5 | c.345T>A p.I115= | Silent (SNP) | VAF 7/172 reads (4%) | called by muse, mutect2
- SPATA5L1 | c.1512T>C p.Y504= | Silent (SNP) | VAF 26/56 reads (46%) | catalogued as COSV59744251; called by muse, mutect2, varscan2
- SPTBN2 | c.2496G>A p.R832= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as COSV100018919; called by muse, mutect2
- SYNPO2 | c.429T>A p.A143= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV61108279; called by muse, mutect2
- USP53 | c.858T>C p.N286= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as rs1427960270, COSV56793328; called by muse, mutect2, varscan2
- ZNF560 | c.1509T>G p.L503= | Silent (SNP) | VAF 61/153 reads (40%) | catalogued as COSV56866688; called by muse, mutect2, varscan2
- FOLH1B | n.1902G>C | RNA (SNP) | VAF 9/42 reads (21%) | called by muse, mutect2, varscan2
